Somatic mutation profile of tumor specimen C3L-02349-01 (aliquot CPT0112540009) from CPTAC case C3L-02349, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 81.0 years (29,600 days).
Specimen C3L-02349-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c68f9253-e240-4cd4-9330-c8d0e90526fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02349-31 (Blood Derived Normal), aliquot CPT0115160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e282cd2-4d13-4e23-bf75-3ea3e4193aa1

The open-access MAF lists 529 somatic variants for this specimen: 364 protein-altering or splice-affecting, 99 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 99, Intron 34, Nonsense Mutation 26, Splice Site 12, RNA 12, Frame Shift Del 10, 5'UTR 8, 3'UTR 6, 5'Flank 5, Splice Region 5, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 110/199 reads (55%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAT2 | c.1102C>A p.H368N | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs1443446432; called by muse, mutect2, varscan2
- ADAMTS20 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67141171; called by muse, mutect2, varscan2
- ADAMTS6 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.168); catalogued as rs1434865692, COSV100068431; called by muse, mutect2, varscan2
- ADCY5 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59203592; called by muse, mutect2, varscan2
- ADGRD1 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV55449750; called by muse, mutect2, varscan2
- AGMO | c.664A>T p.R222W | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61111792; called by muse, mutect2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 70/253 reads (28%) | catalogued as rs748776119, COSV59276444; called by mutect2, pindel, varscan2
- APOA4 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 228/732 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV63360071; called by muse, mutect2, varscan2
- ATG2A | c.2203del p.Q735Rfs*2 | Frame Shift Del (DEL) | VAF 102/350 reads (29%) | catalogued as COSV65967276; called by mutect2, pindel, varscan2
- CAMKMT | c.493-1G>T p.X165_splice | Splice Site (SNP) | VAF 59/161 reads (37%) | catalogued as rs769671764; called by muse, mutect2, varscan2
- CCDC57 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 200/347 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764622642; called by muse, mutect2, varscan2
- CCNF | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 155/342 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs775623319; called by muse, mutect2, varscan2
- CCT7 | c.1579G>C p.V527L | Missense Mutation (SNP) | VAF 250/598 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1424648305; called by muse, mutect2, varscan2
- CD36 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 204/632 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV59209648, COSV99987784; called by muse, mutect2, varscan2
- CDH10 | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1241397517, COSV52577289; called by muse, mutect2, varscan2
- CEBPZ | c.2603+7T>C | Splice Region (SNP) | VAF 14/53 reads (26%) | catalogued as rs1028269706; called by muse, mutect2, varscan2
- CELF5 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 130/377 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as rs973598011, COSV53011370; called by muse, mutect2, varscan2
- CELSR1 | c.6710G>C p.R2237P | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs757607681; called by muse, mutect2, varscan2
- CNNM1 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1427938461; called by muse, mutect2, varscan2
- COPS2 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54645390; called by muse, mutect2
- CPB2 | c.1166C>A p.T389K | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1237191853; called by muse, mutect2, varscan2
- DPP3 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760832117; called by muse, mutect2
- DPP4 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.105); catalogued as rs777468645; called by muse, mutect2, varscan2
- EPHB6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 52/876 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs756659047, COSV67417355, COSV67421793; called by muse, mutect2
- FAM221B | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1213092296; called by muse, mutect2, varscan2
- FAM47A | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs745559073, COSV100649815; called by muse, varscan2
- FEN1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs1208658926; called by muse, mutect2
- FLNC | c.2383G>T p.G795W | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960742; called by muse, mutect2, varscan2
- FMN2 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 49/316 reads (16%) | catalogued as COSV60434920; called by muse, mutect2, varscan2
- FOXI3 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs751117545; called by muse, mutect2, varscan2
- GALC | c.1989G>T p.W663C | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM990622; called by muse, mutect2, varscan2
- GDF11 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 46/654 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs753523328, COSV99143954; called by muse, mutect2
- HACE1 | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99494312; called by muse, varscan2
- HAO1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV66494036; called by mutect2, varscan2
- IGHV1OR21-1 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 34/618 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs1263510282; called by muse, mutect2
- IL7R | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.109); catalogued as COSV100286662; called by muse, varscan2
- KCNN1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as rs745913633; called by muse, mutect2, varscan2
- KLK15 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as rs1203441608, COSV56826139; called by muse, mutect2, varscan2
- KMT2C | c.10633C>T p.Q3545* | Nonsense Mutation (SNP) | VAF 85/223 reads (38%) | catalogued as COSV99030881; called by muse, mutect2, varscan2
- KMT2D | c.6094A>T p.K2032* | Nonsense Mutation (SNP) | VAF 73/206 reads (35%) | catalogued as COSV56419281; called by muse, mutect2, varscan2
- KRT9 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 357/650 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs759592417; called by muse, mutect2, varscan2
- LCT | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 196/473 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51546994; called by muse, mutect2, varscan2
- LGI3 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1238407340; called by muse, mutect2, varscan2
- LONRF2 | c.1755G>A p.A585= | Splice Region (SNP) | VAF 31/290 reads (11%) | catalogued as rs753758939, COSV101111083; called by muse, mutect2, varscan2
- LONRF2 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs762009991; called by muse, mutect2, varscan2
- LRP1B | c.5602C>A p.Q1868K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV67191733; called by muse, mutect2
- LTBP1 | c.3276del p.Q1093Sfs*102 (on ENST00000404816 / NM_206943.4; = p.Q767Sfs*102 on NM_000627.4) | Frame Shift Del (DEL) | VAF 60/372 reads (16%) | catalogued as COSV55379641; called by mutect2, pindel, varscan2
- LYSMD1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 144/270 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.198); catalogued as rs1370240871; called by muse, mutect2, varscan2
- MAEL | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100902023; called by muse, mutect2, varscan2
- MAP3K4 | c.2227G>T p.G743* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV62333853; called by muse, mutect2
- MARCHF3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs778125453, COSV58037601; called by muse, mutect2, varscan2
- MARK1 | c.1329C>G p.N443K | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs751021382; called by muse, mutect2, varscan2
- MTHFD1 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 195/488 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1038153439, COSV53699601; called by muse, mutect2, varscan2
- MTUS2 | c.1714C>A p.P572T | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as COSV70912325; called by muse, mutect2, varscan2
- MUC16 | c.43162G>T p.G14388W | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66691254, COSV66695162; called by muse, mutect2, varscan2
- MYLK3 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1215397927; called by muse, mutect2, varscan2
- MYO3A | c.1994C>A p.P665H | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99781456; called by mutect2, varscan2
- MYO6 | c.3209G>C p.G1070A (on ENST00000369981; = p.G1060A on NM_004999.4) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); catalogued as COSV64118097; called by muse, mutect2, varscan2
- NALCN | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188144130, COSV51918402, COSV99216118; called by muse, mutect2, varscan2
- NAV3 | c.5621C>A p.S1874Y (on ENST00000397909 / NM_001024383.2; = p.S1852Y on NM_014903.6) | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57100094; called by muse, mutect2, varscan2
- NBAS | c.4387G>T p.A1463S | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.114); catalogued as COSV99866456; called by muse, mutect2, varscan2
- NCOR1 | c.6641G>T p.R2214L | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs142105041; called by muse, mutect2, varscan2
- NELL1 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 221/463 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs780264506; called by muse, mutect2, varscan2
- NLRP5 | c.1490C>A p.T497K | Missense Mutation (SNP) | VAF 163/590 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66761858; called by muse, mutect2, varscan2
- NRF1 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV56210078; called by muse, mutect2, varscan2
- OR10J5 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 114/274 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100604856; called by mutect2, varscan2
- OR2M4 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV60708004, COSV60709499; called by muse, mutect2, varscan2
- OR8B8 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV60145191; called by muse, mutect2, varscan2
- OSBP | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1184037322; called by muse, varscan2
- P2RX1 | c.521C>A p.P174Q | Missense Mutation (SNP) | VAF 341/612 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99845004; called by muse, mutect2, varscan2
- PCDH15 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 69/477 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.403); catalogued as rs562377533, COSV57285343; called by muse, mutect2, varscan2
- PCDHB5 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV50669436; called by muse, mutect2, varscan2
- PCSK2 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 48/241 reads (20%) | catalogued as COSV99358388; called by muse, mutect2, varscan2
- PHC3 | c.1025C>G p.S342* (on ENST00000494943 / NM_001308116.2; = p.S354* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 57/377 reads (15%) | catalogued as COSV71948382; called by muse, mutect2, varscan2
- PIGO | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 146/497 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs895003968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R6 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 402/688 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs755690969, COSV61001716; called by muse, mutect2, varscan2
- POMC | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 328/785 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99257096; called by muse, mutect2, varscan2
- PPP1R13L | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62909312; called by muse, mutect2
- PRAMEF20 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 224/575 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs763696662; called by muse, mutect2, varscan2
- PROKR2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 234/764 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs753673244; called by muse, mutect2, varscan2
- PTPRB | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 139/380 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as rs115456633; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1465C>G p.P489A | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99242547; called by muse, mutect2, varscan2
- RAB5A | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56086134; called by muse, mutect2, varscan2
- RGS7 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 45/162 reads (28%) | catalogued as COSV100471887, COSV58541016; called by muse, mutect2, varscan2
- RIMBP2 | c.1778C>A p.P593Q | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99900915; called by muse, mutect2, varscan2
- RNF225 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 178/575 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs983290371; called by muse, mutect2, varscan2
- RYR2 | c.8508C>A p.D2836E | Missense Mutation (SNP) | VAF 111/348 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs757197730, COSV100769884; called by muse, mutect2, varscan2
- SCLT1 | c.1316A>T p.N439I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV55406984; called by muse, mutect2
- SEMA3D | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 140/738 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV52402604; called by muse, mutect2, varscan2
- SH3TC1 | c.3078G>T p.E1026D | Missense Mutation (SNP) | VAF 165/381 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55281055; called by muse, mutect2, varscan2
- SHKBP1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs771613975, COSV52538919; called by muse, mutect2, varscan2
- SHOX2 | c.427A>T p.S143C (on ENST00000441443 / NM_006884.3; = p.S167C on NM_003030.4) | Missense Mutation (SNP) | VAF 206/1327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764001728; called by muse, mutect2, varscan2
- SI | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs569447227, COSV52266598, COSV52293282; called by muse, mutect2, varscan2
- SI | c.3451C>G p.P1151A | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV52300310; called by muse, mutect2, varscan2
- SLC4A3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 100/512 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs372281357; called by muse, mutect2, varscan2
- SLC5A8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs974949950; called by muse, mutect2, varscan2
- SMCO3 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs202090335, COSV53763795, COSV99660873; called by muse, mutect2, varscan2
- SMG8 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1301363568; called by muse, mutect2
- SOX2 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 268/769 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as rs1020751042; called by muse, mutect2, varscan2
- SPOCK2 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748196224, COSV58035717; called by muse, mutect2, varscan2
- SRSF11 | c.1023-1G>C p.X341_splice | Splice Site (SNP) | VAF 32/179 reads (18%) | catalogued as COSV63937352; called by muse, mutect2, varscan2
- STAB2 | c.5663del p.G1888Afs*33 | Frame Shift Del (DEL) | VAF 83/379 reads (22%) | catalogued as rs769244340, COSV66334210; called by mutect2, pindel, varscan2
- STAG3 | c.1798C>G p.P600A | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV57932805; called by muse, mutect2, varscan2
- STARD9 | c.4807A>G p.T1603A | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs1331183041; called by muse, mutect2, varscan2
- STRN3 | c.1890G>T p.K630N (on ENST00000357479 / NM_001083893.2; = p.K546N on NM_014574.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100670352; called by muse, mutect2, varscan2
- SULF2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 226/912 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762002969; called by muse, mutect2, varscan2
- SYNE1 | c.7833G>A p.M2611I (on ENST00000367255 / NM_182961.4; = p.M2618I on NM_033071.3) | Missense Mutation (SNP) | VAF 85/510 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55088706; called by muse, mutect2, varscan2
- TAS2R16 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99972312; called by muse, mutect2, varscan2
- TMEM132D | c.1923G>T p.Q641H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67160836; called by muse, mutect2, varscan2
- TMEM161A | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50776227; called by muse, mutect2, varscan2
- TNKS | c.2047C>G p.R683G | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs1295983183, COSV60056609; called by muse, mutect2
- TNN | c.974C>A p.T325N | Missense Mutation (SNP) | VAF 92/668 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV53421035; called by muse, mutect2, varscan2
- TRIM71 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs771366596; called by muse, varscan2
- TTC21A | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100087268; called by muse, mutect2, varscan2
- TTN | c.10763C>A p.A3588D (on ENST00000591111; = p.A3542D on NM_003319.4) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | catalogued as COSV59977753; called by muse, mutect2, varscan2
- TUT7 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99463664; called by muse, mutect2, varscan2
- VCPKMT | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 129/340 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775696059, COSV99365254; called by muse, mutect2, varscan2
- VPS52 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs377029646; called by muse, mutect2, varscan2
- ZNF180 | c.1596G>A p.W532* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | catalogued as rs893340626; called by muse, mutect2
- ZNF577 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1219842308; called by muse, mutect2, varscan2
- ZNF727 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as rs376201644; called by muse, mutect2, varscan2
- ZNF775 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.729); catalogued as rs752791090; called by muse, mutect2, varscan2
- ABCA4 | c.6728A>G p.Q2243R | Missense Mutation (SNP) | VAF 147/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ABR | c.539A>T p.Q180L (on ENST00000302538 / NM_021962.5; = p.Q143L on NM_001092.5) | Missense Mutation (SNP) | VAF 186/318 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ACAT2 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACMSD | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ACTA1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY1 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ADGRA1 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ADGRB2 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- AK4 | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANKRD2 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- AOX1 | c.2250T>G p.H750Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APOB | c.4420A>T p.K1474* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- APOBEC3A | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 17/466 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- ARFGAP1 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 106/471 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASAP1 | c.2221C>A p.H741N | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ASCC3 | c.6334G>T p.D2112Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ASNS | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ATG2A | c.2204+1G>T p.X735_splice | Splice Site (SNP) | VAF 105/307 reads (34%) | called by mutect2, varscan2
- ATP13A3 | c.3652A>T p.M1218L (on ENST00000645319 / NM_001367549.1; = p.M1188L on NM_024524.3) | Missense Mutation (SNP) | VAF 293/797 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BCKDHB | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BMP5 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- BRCA1 | c.548-1G>T p.X183_splice | Splice Site (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- BRI3BP | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- BTN2A2 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 133/588 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- C2orf72 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.088); called by muse, mutect2
- C4BPA | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CACNA2D1 | c.2768C>T p.S923L (on ENST00000356253 / NM_001366867.1; = p.S911L on NM_000722.4) | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CD163 | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 131/318 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC27 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDC45 | c.1386G>T p.R462S | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CDH26 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CEACAM3 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CEP55 | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CFAP410 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CFAP46 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 57/210 reads (27%) | called by muse, mutect2, varscan2
- CFAP46 | c.2123C>A p.T708N | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP61 | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP73 | c.575G>C p.R192P | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CFAP91 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP91 | c.825G>T p.R275S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFHR3 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 161/705 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CHL1 | c.879G>T p.K293N (on ENST00000397491 / NM_001253387.1; = p.K309N on NM_006614.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, varscan2
- CHRNA2 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 123/435 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CIB2 | c.542+7C>T | Splice Region (SNP) | VAF 153/417 reads (37%) | called by muse, mutect2, varscan2
- CLNK | c.1054T>A p.Y352N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- CLNK | c.1052T>G p.F351C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL18A1 | c.2354G>T p.C785F (on ENST00000359759 / NM_130444.3; = p.C550F on NM_030582.4) | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- COL6A5 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CTNND2 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CYP2C18 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DBT | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DCSTAMP | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DMC1 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAAF3 | c.739G>T p.A247S (on ENST00000524407 / NM_001256715.2; = p.A294S on NM_178837.4) | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.8245C>G p.L2749V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DNAI3 | c.1481T>G p.I494S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- DNAJC5G | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 101/661 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DZIP3 | c.3363G>C p.W1121C | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ECHDC2 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ECT2L | c.2686A>T p.N896Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EFCAB6 | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- EHHADH | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- EML3 | c.1983-1G>C p.X661_splice | Splice Site (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- ESPL1 | c.5133G>T p.L1711F | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EYA4 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FADD | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM214B | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FARP1 | c.2232G>C p.K744N | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FAS | c.403dup p.C135Lfs*2 | Frame Shift Ins (INS) | VAF 36/125 reads (29%) | called by mutect2, varscan2
- FAT3 | c.9626A>T p.D3209V | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN1 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- FBN3 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FCHO1 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 115/290 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FLG | c.10175C>G p.T3392S | Missense Mutation (SNP) | VAF 162/1135 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- FOXL2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 328/1076 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FUBP1 | c.1018dup p.T340Nfs*11 | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | called by mutect2, pindel, varscan2
- FZD7 | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 284/689 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GALC | c.1988G>T p.W663L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- GCN1 | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- GFI1B | c.479T>G p.M160R | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GFM1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GIGYF2 | c.3388A>G p.K1130E | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GLI2 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 272/791 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, varscan2
- GOT1L1 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GPC5 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- GPR156 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR17 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.07); called by muse, mutect2
- GRIP2 | c.1837A>G p.T613A (on ENST00000619221; = p.T516A on NM_001080423.4) | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- GUCY1A1 | c.849C>A p.C283* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- HDGFL2 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 137/370 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HELZ2 | c.2761T>G p.F921V (on ENST00000467148 / NM_001037335.2; = p.F352V on NM_033405.3) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- HERC2 | c.9164-1G>T p.X3055_splice | Splice Site (SNP) | VAF 115/333 reads (35%) | called by muse, mutect2, varscan2
- HERC2 | c.8002del p.V2668Lfs*2 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- HHLA1 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- HLA-DRB1 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 78/600 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HOXC11 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 124/440 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- HOXD4 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 193/490 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HPX | c.997G>C p.G333R | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HR | c.2369A>G p.D790G | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTR2C | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV1OR21-1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 92/1220 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- IGKV1-8 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 115/659 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IGKV5-2 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ITPA | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 76/261 reads (29%) | called by muse, mutect2, varscan2
- KALRN | c.79A>G p.S27G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- KCNC2 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH8 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1328 | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLF15 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 90/450 reads (20%) | called by muse, mutect2, varscan2
- KPNA5 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- KRTAP10-6 | c.255C>A p.C85* | Nonsense Mutation (SNP) | VAF 73/403 reads (18%) | called by muse, mutect2, varscan2
- LHX2 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 150/417 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LIMK2 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LMAN1 | c.1494T>A p.Y498* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- LMLN | c.1048-2A>G p.X350_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2
- LMNA | c.1969-5C>T | Splice Region (SNP) | VAF 155/1034 reads (15%) | called by muse, mutect2, varscan2
- LTF | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAPK6 | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- MED13L | c.1485A>T p.E495D | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS1 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MFHAS1 | c.1613A>C p.H538P | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MFN1 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- MKLN1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 106/283 reads (37%) | called by muse, mutect2, varscan2
- MKRN3 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MTNR1B | c.33C>A p.C11* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- NCAM2 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCAPD3 | c.3025G>C p.E1009Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NEUROD6 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKTR | c.930-2A>T p.X310_splice | Splice Site (SNP) | VAF 26/35 reads (74%) | called by muse, mutect2, varscan2
- NLGN1 | c.581del p.G194Efs*10 | Frame Shift Del (DEL) | VAF 27/201 reads (13%) | called by mutect2, pindel, varscan2
- NPHS1 | c.1319C>G p.P440R | Missense Mutation (SNP) | VAF 133/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR2C1 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRG3 | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NRG3 | c.1907T>G p.V636G (on ENST00000404547 / NM_001370084.1; = p.V612G on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/284 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NRK | c.2385G>T p.Q795H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN1 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NTM | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- OR10J5 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2AG1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- OR2T29 | c.252del p.M85Cfs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- OR51T1 | c.212T>A p.V71D | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PARD3B | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDH15 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH17 | c.2624G>T p.S875I | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- PCDH9 | c.1912C>A p.Q638K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB9 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PCLO | c.13559G>T p.G4520V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNT | c.6559G>C p.D2187H | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PDXK | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PFDN2 | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- PICALM | c.163A>T p.N55Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PKDREJ | c.5157C>G p.I1719M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PKHD1 | c.10142C>A p.S3381Y | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PKHD1 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PLK5 | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLOD2 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR4 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PLPPR4 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PNMA2 | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLB | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); called by muse, mutect2
- POMC | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 323/775 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM8 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 185/493 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRR23C | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR23C | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS21 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS53 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PRSS56 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- PSKH2 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPRD | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- PTPRM | c.2269T>A p.F757I | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PXDN | c.2461T>G p.W821G | Missense Mutation (SNP) | VAF 68/1264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM20 | c.3019G>T p.E1007* | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- RHAG | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 141/602 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- RNF149 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF40 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RUNDC3B | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SAXO2 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SBNO2 | c.1463del p.F488Sfs*27 | Frame Shift Del (DEL) | VAF 39/346 reads (11%) | called by mutect2, pindel, varscan2
- SCN10A | c.5714T>A p.L1905H | Missense Mutation (SNP) | VAF 232/426 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SECISBP2L | c.1434A>T p.K478N (on ENST00000559471 / NM_001193489.2; = p.K433N on NM_014701.4) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEPTIN8 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SH2D1A | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SLC17A8 | c.910del p.S304Vfs*32 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- SLC17A8 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A24 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC37A4 | c.623A>T p.K208M | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- SLC4A2 | c.2383T>A p.W795R | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 172/861 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC9A7 | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SLCO5A1 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA33 | c.34+3G>C | Splice Region (SNP) | VAF 61/222 reads (27%) | called by muse, mutect2, varscan2
- SSRP1 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- STAB1 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STK31 | c.1293+1G>A p.X431_splice | Splice Site (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- STXBP5L | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STYXL2 | c.3277A>C p.M1093L | Missense Mutation (SNP) | VAF 81/531 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBC1D32 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- TCTN1 | c.1214del p.N405Ifs*18 (on ENST00000551590 / NM_001173975.3; = p.N391Ifs*18 on NM_024549.6) | Frame Shift Del (DEL) | VAF 63/260 reads (24%) | called by mutect2, pindel, varscan2
- TDRD15 | c.2616dup p.S873* | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- TDRD15 | c.5330C>A p.P1777H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TEK | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 67/537 reads (12%) | called by muse, mutect2, varscan2
- THSD7A | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TLK1 | c.146T>C p.M49T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- TMEM132E | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 479/825 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TMEM178A | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM273 | c.97+2T>A p.X33_splice | Splice Site (SNP) | VAF 59/332 reads (18%) | called by muse, mutect2, varscan2
- TNRC18 | c.4479G>T p.Q1493H | Missense Mutation (SNP) | VAF 152/351 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TNS2 | c.1534G>T p.D512Y (on ENST00000314250 / NM_170754.4; = p.D522Y on NM_015319.2) | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TREX2 | c.542T>G p.L181R (on ENST00000334497; = p.L138R on NM_080701.3) | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, varscan2
- TRRAP | c.10631G>A p.R3544H (on ENST00000359863 / NM_001244580.1; = p.R3515H on NM_003496.3) | Missense Mutation (SNP) | VAF 234/782 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN15 | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TTN | c.29451G>A p.M9817I (on ENST00000591111; = p.M8890I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UNC13D | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- UNC45A | c.2246A>C p.Q749P | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- UNC5D | c.2119A>C p.N707H | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- USP6 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 430/776 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- USP8 | c.573G>C p.M191I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- USP9X | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VIRMA | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- VWA3B | c.3627G>C p.K1209N | Missense Mutation (SNP) | VAF 121/510 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- WIF1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 132/595 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- WNT1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 81/319 reads (25%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YBX1 | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 87/499 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZMYM3 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF165 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF239 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF253 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF573 | c.707A>G p.H236R (on ENST00000536220 / NM_001172692.1; = p.H178R on NM_152360.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF667 | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZNF676 | c.131-1G>C p.X44_splice (on ENST00000650058; = p.X12_splice on NM_001001411.3) | Splice Site (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ZNF75D | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ZNF850 | c.1695A>T p.E565D | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNRF3 | c.2570G>T p.G857V (on ENST00000544604 / NM_001206998.2; = p.G757V on NM_032173.3) | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ZZEF1 | c.1968A>C p.E656D | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ABHD17C | c.723G>T p.V241= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- AC004922.1 | c.1827G>A p.G609= | Silent (SNP) | VAF 109/336 reads (32%) | catalogued as rs1178975222, COSV99402934; called by muse, mutect2, varscan2
- ACMSD | c.510C>A p.S170= | Silent (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- ACOT11 | c.579C>T p.D193= | Silent (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- AGT | c.1257C>T p.I419= | Silent (SNP) | VAF 101/739 reads (14%) | called by muse, mutect2, varscan2
- ANHX | c.906G>A p.R302= | Silent (SNP) | VAF 102/507 reads (20%) | called by muse, mutect2, varscan2
- ATP1A3 | c.840G>A p.L280= (on ENST00000545399 / NM_001256214.2; = p.L267= on NM_152296.5) | Silent (SNP) | VAF 89/340 reads (26%) | called by muse, mutect2, varscan2
- B4GALT5 | c.42G>T p.S14= | Silent (SNP) | VAF 139/462 reads (30%) | called by muse, mutect2, varscan2
- CC2D1A | c.1929C>T p.F643= | Silent (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- CCDC74A | c.504C>T p.S168= | Silent (SNP) | VAF 149/437 reads (34%) | catalogued as rs777029211; called by muse, mutect2, varscan2
- CDCA7 | c.481A>C p.R161= (on ENST00000347703 / NM_145810.3; = p.R240= on NM_031942.5) | Silent (SNP) | VAF 112/292 reads (38%) | called by muse, varscan2
- CDK8 | c.981A>G p.E327= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- CILK1 | c.426A>T p.A142= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- CYP26B1 | c.492G>T p.V164= | Silent (SNP) | VAF 234/880 reads (27%) | called by muse, mutect2, varscan2
- DDX54 | c.273G>A p.K91= | Silent (SNP) | VAF 118/536 reads (22%) | called by muse, varscan2
- DST | c.21165G>A p.R7055= (on ENST00000361203 / NM_001374722.1; = p.R4752= on NM_015548.5) | Silent (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- DZIP1L | c.33C>T p.L11= | Silent (SNP) | VAF 57/310 reads (18%) | catalogued as COSV59524600; called by muse, mutect2, varscan2
- ECRG4 | c.193C>T p.L65= | Silent (SNP) | VAF 137/507 reads (27%) | catalogued as COSV53000930; called by muse, mutect2, varscan2
- EIF5B | c.3405C>T p.I1135= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1165203240, COSV51481708, COSV51491737; called by muse, mutect2, varscan2
- ENTPD1 | c.78C>T p.I26= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV64603990; called by muse, mutect2, varscan2
- ESYT3 | c.553A>C p.R185= | Silent (SNP) | VAF 93/736 reads (13%) | called by muse, mutect2, varscan2
- FAT4 | c.5322C>G p.L1774= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- FREM2 | c.3450G>A p.Q1150= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- GAB2 | c.114G>C p.R38= | Silent (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- GALNT13 | c.1665C>A p.G555= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1354481866; called by muse, mutect2, varscan2
- GFRA1 | c.165C>T p.G55= | Silent (SNP) | VAF 78/482 reads (16%) | catalogued as COSV62612001; called by muse, mutect2, varscan2
- GNPAT | c.1443T>C p.Y481= | Silent (SNP) | VAF 258/576 reads (45%) | catalogued as rs376773292; called by muse, varscan2
- GORASP2 | c.1068A>G p.A356= | Silent (SNP) | VAF 38/432 reads (9%) | called by muse, mutect2
- GPRC6A | c.807C>A p.A269= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV59952820; called by muse, mutect2, varscan2
- GRK5 | c.1689C>G p.S563= | Silent (SNP) | VAF 42/230 reads (18%) | catalogued as COSV100962805; called by muse, varscan2
- GSS | c.987C>T p.A329= | Silent (SNP) | VAF 142/432 reads (33%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1197C>G p.L399= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs190526971; called by muse, mutect2, varscan2
- HCRTR2 | c.486T>C p.F162= | Silent (SNP) | VAF 181/646 reads (28%) | called by muse, mutect2, varscan2
- HORMAD1 | c.1146A>G p.P382= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- HTR5A | c.1005C>A p.P335= | Silent (SNP) | VAF 52/286 reads (18%) | catalogued as rs1370819105; called by muse, mutect2, varscan2
- IGKV1-8 | c.162C>A p.A54= | Silent (SNP) | VAF 118/667 reads (18%) | called by muse, mutect2, varscan2
- IGKV6D-21 | c.204G>A p.K68= | Silent (SNP) | VAF 171/687 reads (25%) | catalogued as rs1359921862; called by muse, mutect2, varscan2
- IGLV1-50 | c.282G>T p.L94= | Silent (SNP) | VAF 76/388 reads (20%) | called by muse, mutect2, varscan2
- JHY | c.1776G>A p.T592= | Silent (SNP) | VAF 148/446 reads (33%) | catalogued as rs776711079, COSV99913807; called by muse, mutect2, varscan2
- JUP | c.165C>G p.L55= | Silent (SNP) | VAF 24/877 reads (3%) | called by muse, mutect2
- KCNJ10 | c.57C>A p.P19= | Silent (SNP) | VAF 110/733 reads (15%) | called by muse, mutect2, varscan2
- KCNQ2 | c.627C>A p.I209= | Silent (SNP) | VAF 84/311 reads (27%) | catalogued as rs749602639; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ2 | c.87C>G p.P29= | Silent (SNP) | VAF 125/437 reads (29%) | called by muse, mutect2, varscan2
- LARP1 | c.2199G>A p.Q733= (on ENST00000518297 / NM_033551.3; = p.Q656= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 121/317 reads (38%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.276C>T p.T92= | Silent (SNP) | VAF 97/377 reads (26%) | catalogued as rs1274616200, COSV58186443; called by muse, mutect2, varscan2
- MAGEB4 | c.360G>T p.L120= | Silent (SNP) | VAF 60/140 reads (43%) | called by muse, mutect2, varscan2
- MDFI | c.471C>G p.L157= | Silent (SNP) | VAF 52/161 reads (32%) | called by muse, mutect2, varscan2
- ME1 | c.393G>T p.G131= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- MED25 | c.1533C>G p.L511= | Silent (SNP) | VAF 198/691 reads (29%) | called by muse, mutect2, varscan2
- MPEG1 | c.591G>C p.L197= | Silent (SNP) | VAF 52/420 reads (12%) | catalogued as rs370351139; called by muse, mutect2, varscan2
- MROH2A | c.3240C>G p.V1080= | Silent (SNP) | VAF 74/208 reads (36%) | called by muse, mutect2, varscan2
- MTHFD1L | c.564G>T p.G188= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- NECTIN3 | c.105G>T p.T35= | Silent (SNP) | VAF 86/379 reads (23%) | called by muse, mutect2, varscan2
- NRCAM | c.2623C>A p.R875= (on ENST00000379028 / NM_001371124.1; = p.R859= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 47/265 reads (18%) | called by muse, mutect2, varscan2
- OR2AP1 | c.141C>A p.T47= | Silent (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- OR2J1 | c.351G>T p.V117= | Silent (SNP) | VAF 90/247 reads (36%) | called by muse, mutect2, varscan2
- OR4K17 | c.798T>C p.S266= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- OR52A1 | c.558C>A p.A186= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV61092172; called by muse, mutect2, varscan2
- OR6P1 | c.492C>T p.S164= | Silent (SNP) | VAF 155/351 reads (44%) | called by muse, mutect2, varscan2
- OR8B8 | c.792T>A p.S264= | Silent (SNP) | VAF 45/172 reads (26%) | called by muse, mutect2, varscan2
- OSBP | c.255G>T p.G85= | Silent (SNP) | VAF 83/396 reads (21%) | called by muse, mutect2, varscan2
- OTOL1 | c.507G>T p.P169= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV60006977; called by muse, mutect2, varscan2
- P2RX3 | c.513C>T p.F171= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- PAX7 | c.1335C>A p.P445= | Silent (SNP) | VAF 147/328 reads (45%) | called by muse, mutect2, varscan2
- PIGL | c.277T>C p.L93= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs778047142; called by muse, mutect2, varscan2
- PIK3R5 | c.612C>T p.T204= | Silent (SNP) | VAF 215/380 reads (57%) | called by muse, mutect2, varscan2
- PKHD1 | c.10143C>A p.S3381= | Silent (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1878G>A p.R626= (on ENST00000379409; = p.R574= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/234 reads (21%) | catalogued as COSV100379205; called by muse, mutect2, varscan2
- PLXNC1 | c.486G>T p.T162= | Silent (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- PNMA2 | c.852C>A p.A284= | Silent (SNP) | VAF 73/240 reads (30%) | called by muse, mutect2, varscan2
- POLE | c.3531C>G p.V1177= | Silent (SNP) | VAF 45/179 reads (25%) | called by muse, mutect2, varscan2
- PRDM6 | c.1368C>T p.S456= | Silent (SNP) | VAF 72/203 reads (35%) | catalogued as COSV68335627; called by muse, mutect2, varscan2
- PSG1 | c.363C>A p.T121= | Silent (SNP) | VAF 64/233 reads (27%) | catalogued as COSV54954521; called by muse, mutect2, varscan2
- RALGDS | c.990G>A p.A330= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as rs142210289; called by muse, mutect2, varscan2
- RNF213 | c.1173C>T p.F391= | Silent (SNP) | VAF 20/511 reads (4%) | called by muse, mutect2
- RP1L1 | c.2475C>T p.C825= | Silent (SNP) | VAF 64/264 reads (24%) | called by muse, mutect2, varscan2
- RTF1 | c.498T>C p.S166= | Silent (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- RTP5 | c.840C>A p.I280= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- RYR3 | c.9738A>T p.A3246= (on ENST00000389232; = p.A3247= on NM_001036.6) | Silent (SNP) | VAF 80/511 reads (16%) | called by muse, mutect2, varscan2
- SCG5 | c.363T>C p.P121= | Silent (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2
- SI | c.4956C>A p.P1652= | Silent (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- SLC18B1 | c.780C>G p.L260= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- SLC25A11 | c.33G>T p.G11= | Silent (SNP) | VAF 32/490 reads (7%) | catalogued as rs545975633; called by muse, mutect2
- SLC50A1 | c.174G>C p.L58= | Silent (SNP) | VAF 60/342 reads (18%) | called by muse, mutect2, varscan2
- SLC9C1 | c.1630T>C p.L544= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV59891123; called by muse, mutect2, varscan2
- SNRPA1 | c.642G>C p.L214= | Silent (SNP) | VAF 46/352 reads (13%) | called by muse, mutect2, varscan2
- STRA8 | c.357G>A p.G119= (on ENST00000275764; = p.G97= on NM_182489.2) | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- TERT | c.786G>C p.T262= | Silent (SNP) | VAF 49/755 reads (6%) | catalogued as COSV99717431; called by muse, mutect2
- THADA | c.849C>T p.C283= | Silent (SNP) | VAF 123/503 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.61344C>T p.G20448= (on ENST00000591111; = p.G13024= on NM_003319.4) | Silent (SNP) | VAF 184/457 reads (40%) | called by muse, mutect2, varscan2
- UBE4A | c.2619G>T p.L873= (on ENST00000252108 / NM_001204077.2; = p.L880= on NM_004788.4) | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- USH2A | c.11178G>T p.L3726= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- VN1R4 | c.258C>A p.L86= | Silent (SNP) | VAF 65/208 reads (31%) | called by muse, mutect2, varscan2
- VSX1 | c.93C>T p.F31= | Silent (SNP) | VAF 240/773 reads (31%) | catalogued as COSV65021564; called by muse, mutect2, varscan2
- XKR7 | c.1644C>A p.I548= | Silent (SNP) | VAF 89/376 reads (24%) | catalogued as COSV73813384; called by muse, mutect2, varscan2
- ZAN | c.2412C>A p.P804= | Silent (SNP) | VAF 80/205 reads (39%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10377T>C p.N3459= | Silent (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- ZMYM3 | c.2289G>A p.Q763= | Silent (SNP) | VAF 100/203 reads (49%) | called by muse, mutect2, varscan2
- ZNF485 | c.198G>T p.G66= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- ABCC13 | n.3732T>C | RNA (SNP) | VAF 5/44 reads (11%) | catalogued as rs867493398; called by muse, mutect2
- AC004696.1 | chr19:56495052 C>A | 5'Flank (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ACADM | chr1:75724692 C>T | 5'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- ADAM23 | c.2360-4097A>G | Intron (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- AOX1 | c.-10G>C | 5'UTR (SNP) | VAF 69/586 reads (12%) | called by muse, mutect2, varscan2
- AP3B2 | c.360+228C>G | Intron (SNP) | VAF 33/215 reads (15%) | catalogued as rs1401647926; called by muse, mutect2, varscan2
- AXDND1 | c.1798+3940C>A | Intron (SNP) | VAF 76/547 reads (14%) | catalogued as rs1448188502; called by muse, mutect2, varscan2
- CD300LD | chr17:74592584 C>A | 5'Flank (SNP) | VAF 153/250 reads (61%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93733251 T>G | 3'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- CFAP65 | c.542+15del | Intron (DEL) | VAF 145/476 reads (30%) | catalogued as COSV55389956; called by mutect2, pindel, varscan2
- CHKB | c.224+58G>A | Intron (SNP) | VAF 78/222 reads (35%) | called by muse, mutect2, varscan2
- CPED1 | c.2311-4560T>A | Intron (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- CRTAP | c.*38G>T | 3'UTR (SNP) | VAF 48/97 reads (49%) | catalogued as COSV100310232; called by muse, mutect2, varscan2
- CSF2RA | c.*295G>T | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, varscan2
- DEK | c.-77G>A | 5'UTR (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- EI24P4 | n.910T>C | RNA (SNP) | VAF 64/447 reads (14%) | called by muse, mutect2, varscan2
- EIF2B1 | c.482+95C>G | Intron (SNP) | VAF 12/359 reads (3%) | called by muse, mutect2
- FLJ40194 | n.331G>T | RNA (SNP) | VAF 46/592 reads (8%) | catalogued as rs748009307; called by muse, mutect2
- FTH1 | chr11:61968317 C>G | 5'Flank (SNP) | VAF 118/322 reads (37%) | called by muse, mutect2, varscan2
- GBP1 | c.1471+17G>C | Intron (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- GNG5P2 | n.185A>G | RNA (SNP) | VAF 74/177 reads (42%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+416C>A | Intron (SNP) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- GRK5 | c.*10T>C | 3'UTR (SNP) | VAF 112/492 reads (23%) | catalogued as rs1274050319; called by muse, varscan2
- GUSB | c.913-26C>G | Intron (SNP) | VAF 132/635 reads (21%) | called by muse, mutect2, varscan2
- HECW1 | c.-124G>T | 5'UTR (SNP) | VAF 104/220 reads (47%) | called by muse, varscan2
- HNF4G | c.-23-3764T>A | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- KCNQ1 | c.*325G>T | 3'UTR (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- KRT17P1 | n.289G>T | RNA (SNP) | VAF 76/477 reads (16%) | called by muse, mutect2, varscan2
- KRT17P1 | n.288G>C | RNA (SNP) | VAF 77/482 reads (16%) | catalogued as rs773426476; called by muse, mutect2, varscan2
- LILRB5 | c.1307-29C>A | Intron (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- LINC01036 | n.255G>T | RNA (SNP) | VAF 95/728 reads (13%) | called by muse, mutect2, varscan2
- LINC01511 | n.437-8470C>A | Intron (SNP) | VAF 39/188 reads (21%) | called by muse, varscan2
- LIPC | c.88+4738C>A | Intron (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- LIPT2 | chr11:74497602 G>C | 5'Flank (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- MATR3 | c.2149-36G>C | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- MEIS3P1 | n.860C>T | RNA (SNP) | VAF 200/727 reads (28%) | called by muse, mutect2, varscan2
- MIR206 | n.10A>T | RNA (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- MRPS11 | c.65+11A>C | Intron (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- NTRK1 | c.1502-40C>A | Intron (SNP) | VAF 105/563 reads (19%) | called by muse, mutect2, varscan2
- PARP15 | c.772-468G>A | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- PDLIM2 | c.-380G>T | 5'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- PHACTR3 | c.-2C>A | 5'UTR (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- PHB2 | c.712-94C>T | Intron (SNP) | VAF 65/124 reads (52%) | catalogued as COSV99781234; called by muse, mutect2, varscan2
- PKN3 | c.-33G>A | 5'UTR (SNP) | VAF 95/248 reads (38%) | catalogued as rs761577062; called by muse, varscan2
- PLSCR2 | c.-29G>C | 5'UTR (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- POLR2F | c.452+1001G>T | Intron (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- SH3D21 | c.727-27C>T | Intron (SNP) | VAF 20/96 reads (21%) | catalogued as rs181543739; called by mutect2, varscan2
- SHANK1 | c.2390-221C>A | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SLC30A3 | c.*182T>A | 3'UTR (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- SPAG4 | c.476+15C>A | Intron (SNP) | VAF 88/282 reads (31%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.624G>T | RNA (SNP) | VAF 80/516 reads (16%) | called by muse, mutect2, varscan2
- SPATA8 | n.777A>G | RNA (SNP) | VAF 80/375 reads (21%) | catalogued as rs1462525969; called by muse, mutect2, varscan2
- ST8SIA4 | c.113+2404A>G | Intron (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- SYNJ1 | c.95+35G>T | Intron (SNP) | VAF 105/246 reads (43%) | called by muse, mutect2, varscan2
- TAFA2 | c.385-10491C>T | Intron (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- TBCA | c.54-6900G>T | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2
- TERT | c.2843+49G>T | Intron (SNP) | VAF 79/337 reads (23%) | called by muse, mutect2, varscan2
- TEX35 | c.90+88A>T | Intron (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- TEX51 | c.274+11C>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- TMEM151A | c.-28C>G | 5'UTR (SNP) | VAF 83/433 reads (19%) | called by muse, mutect2, varscan2
- TOX3 | c.*266C>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99567988; called by muse, mutect2, varscan2
- TUBB8P7 | n.894+143C>A | Intron (SNP) | VAF 149/533 reads (28%) | called by muse, mutect2, varscan2
- UROD | c.637-15C>A | Intron (SNP) | VAF 100/345 reads (29%) | catalogued as COSV99870145; called by muse, mutect2, varscan2
- WDR62 | c.2971+21G>A | Intron (SNP) | VAF 243/671 reads (36%) | called by muse, mutect2, varscan2
- WDR73 | c.352+18G>C | Intron (SNP) | VAF 115/287 reads (40%) | called by muse, mutect2, varscan2
- ZNF849P | n.699A>G | RNA (SNP) | VAF 39/88 reads (44%) | catalogued as rs778740765; called by muse, mutect2, varscan2
